Somatic mutation profile of tumor specimen 0DPMRQ from CCDI case PBCDKR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,554 days).
Specimen 0DPMRQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2671bc8c-0700-426c-8423-7e9fd3df97ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/563b8eab-945e-44d6-bc59-80feaebb538c

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN3A | c.3445C>A p.P1149T | Missense Mutation (SNP) | VAF 23/736 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV51800601; called by muse, mutect2
- ZFHX3 | c.2645C>T p.S882L | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs201144589; called by muse, mutect2, varscan2
- ANKS1B | c.1705A>T p.T569S | Missense Mutation (SNP) | VAF 84/481 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by mutect2, varscan2
- CNDP2 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ENPP2 | c.876G>T p.W292C | Missense Mutation (SNP) | VAF 149/335 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL3RA | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 70/301 reads (23%) | called by muse, mutect2, varscan2
- MDN1 | c.14450del p.D4817Vfs*37 | Frame Shift Del (DEL) | VAF 320/510 reads (63%) | called by mutect2, varscan2
- MYO18A | c.3460G>C p.E1154Q | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.216); called by muse, mutect2
- PITX1 | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SMCP | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.653); called by mutect2, varscan2
- ALKBH5 | c.42C>G p.L14= | Silent (SNP) | VAF 34/208 reads (16%) | called by mutect2, varscan2
- CEP78 | c.2034T>C p.S678= (on ENST00000424347 / NM_001349840.2; = p.S679= on NM_032171.3) | Silent (SNP) | VAF 141/495 reads (28%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.2196C>T p.R732= (on ENST00000295902; = p.R676= on NM_198859.4) | Silent (SNP) | VAF 98/310 reads (32%) | catalogued as rs985544704, COSV55772441; called by muse, mutect2, varscan2
- SIM2 | c.1291C>T p.L431= | Silent (SNP) | VAF 11/299 reads (4%) | catalogued as COSV99293591; called by muse, mutect2
- SLC30A5 | c.274-525T>C | Intron (SNP) | VAF 44/187 reads (24%) | catalogued as rs1181307403; called by muse, mutect2, varscan2
